Gene-level copy-number profile of tumor specimen TCGA-ER-A19N-06A from TCGA case TCGA-ER-A19N, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.9 years (17,480 days).
Specimen TCGA-ER-A19N-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.766a3474-a0ae-4ab7-807b-083f4000be70.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf392319-d164-44e9-b68b-554fe4622dfd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 208; copy number 2: 4,940; copy number 3: 1,144; copy number 4: 36,375; copy number 5: 110; copy number 6: 12,280; copy number 7: 1,518; copy number 8: 35; copy number 9: 784; copy number 10: 930; copy number 11: 1,491.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19N-06A-11D-A191-01): tumor purity 0.35, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 208 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–15,146,401, 200 genes (broad region; genes not listed).
- chr9:21,638,285–22,029,594, 8 genes (within-gene range 0–2): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,205 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–55,579,197, 1,491 genes, copy number 11 (broad region; genes not listed).
- chr8:95,204,456–95,811,254, 1 gene, copy number 9 (within-gene range 6–9): C8orf37-AS1.
- chr8:95,505,406–145,066,685, 783 genes, copy number 9 (broad region; genes not listed).
- chr17:51,153,559–83,095,122, 930 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
